FM case AD2336 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/31858eb0-30a1-4dab-9d3e-f37509f44592

Male, 58.6 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
